Surgical pathology report (de-identified scan), TCGA case TCGA-49-AARQ, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-AARQ-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

=====

INTERPRETATION AND DIAGNOSIS:

1. RIGHT UPPER LOBE (LOBECTOMY): TWO (2) SEPARATE NON-CONTIGUOUS FOCI OF INFILTRATING MODERATELY DIFFERENTIATED ADENOCARCINOMA (3.2 CM AND 1.0 CM). THE TUMOR DOES NOT EXTEND TO THE OVERLYING PLEURAL SURFACE. BRONCHIAL MARGINS, VASCULAR MARGINS, PARENCHYMAL MARGINS, AND SIX (6) HILAR LYMPH NODES ARE NEGATIVE FOR TUMOR. THE PATHOLOGIC STAGE OF THE TUMOR IS pT2N0Mx, STAGE I. ACUTE AND ORGANIZING BRONCHOPNEUMONIA IN THE AREA SURROUNDING THE TUMOR (FOCAL OBSTRUCTIVE PNEUMONITIS). EMPHYSEMATOUS CHANGES WITH FOCAL PERIPHERAL BULLA FORMATION. SEE NOTE.
2. STATION R-4 LYMPH NODE (BX): ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR.
3. STATION 7 LYMPH NODE (BX): ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR.

NOTE: The measured tumor size is corrected for surrounding pneumonia.

*Electronic signature

=====

Clinical History:

NON SMALL CELL CARCINOMA OF THE LUNG.

GROSS DESCRIPTION

(Continued on next page.)

ICD-O.3
Adenocarcinoma NOS 8140/3
Site: R Lung, upper lobe C34.1
JW 5/20/14

[page 2 of 3]
PART #1: FS: RIGHT UPPER LOBE
Resident Pathologist:

FROZEN SECTION DIAGNOSIS --

FS: RIGHT UPPER LOBE: STAPLED MARGIN NEGATIVE FOR TUMOR.

The specimen is received fresh labeled [REDACTED] and designated right upper lobe. It consists of a grossly recognizable lobe of lung that weighs 250 gms, and measures 20 x 9.5 x 3.5 cm. The staple parenchymal margin measures 17 cm in length. The entire parenchymal margin will be sampled for histology. One particular area of concern raised by the surgeon was frozen with frozen section diagnosis as above. There is in fact some firmness felt underneath the parenchymal margin. Upon serially sectioning through the lung, this area of firmness appears to be secondary to bronchopneumonia. A tumor mass is identified which measures 3.2 cm in greatest dimension. This white tan tumor mass approaches the parenchymal margin no closer than 4.2 cm. Between this nodule and the overlying stapled parenchymal margin is the area of firmness consistent with bronchopneumonia. There is however one additional smaller nodule that is white tan in color measuring 1.0 cm in greatest dimension. This other nodule is separate from the main tumor nodule. This nodule is surrounded by the firm gray tan tissue reminiscent of pneumonia. This second nodule approaches the stapled parenchymal margin, no closer than 2.2 cm. The bronchial and vascular margins grossly appears well away from the tumor and approach no closer than 4.0 cm from the main tumor mass, and 6.2 cm from the other suspicious smaller nodule. In the area of the lung adjacent to the tumor in the area away from the pneumonia. the lung appears focally cystic. The remainder of the lung specimen is congested. No other lesions are identified. Black and white and color photographs of the specimen are taken. In one region the tumor appears grossly to approach the overlying pleural surface with some of focal hardening and puckering of the surface. Representative sections are submitted.

SUMMARY OF SECTIONS:

6	- LN1-6	- 2 EA.	(ONE NODE PER CASSETTE)
1	- FSC	- 1 EA.	(FROZEN CONTROL OF PARENCHYMAL MARGIN)
1	- VM	- 1	(VASCULAR MARGIN)
1	- BM	- 1	(BRONCHIAL MARGIN)
3	- PM1-3	- M	(REMAINDER OF PARENCHYMAL MARGIN, NOT FROZEN)

(Continued on next page.)

[page 3 of 3]
=====

3	- A-C	- 3,2,2	(PLEURA OVERLYING TUMOR, TUMOR IS SEEN IN SECTION C)
3	- D-F	- 1	(TUMOR WITH ADJACENT CYSTIC LUNG)
2	- G-H	- 1 EA.	(TUMOR WITH ADJACENT FIRM LUNG)
1	- I	- 2	(REPRESENTATIVE TUMOR)
1	- J	- 1	(SECOND NODULE)
2	- K-L	- 1	(FIRM LUNG WITH ADJACENT MORE NORMAL LUNG)
1	- M	- 1	(REPRESENTATIVE FIRM LUNG)
4	- N-Q	- 2,3,1,1	(REPRESENTATIVE CYSTIC LUNG)
3	- R-T	- 2,2,1	(OTHER REPRESENTATIVE LUNG)
32	- TOTAL	- M	

PART #2: R-4 LYMPH NODE
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated R-4 lymph node. It consists of one piece of red-tan soft tissue measuring 1 x 0.5 x 0.3 cm. The specimen is bisected and submitted in its entirety.

SUMMARY OF SECTIONS:

1 - A - 2
1 - TOTAL - 2

PART #3: STATION 7 LYMPH NODE
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated station 7 lymph node. It consists of one piece of red-black to tan soft tissue measuring 0.7 x 0.5 x 0.2 cm. The specimen is bisected and entirely submitted.

SUMMARY OF SECTIONS:

1 - A - 2
1 - TOTAL - 2

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printe

Criteria	W 11/8/14	Yes	No

Source: NCI Genomic Data Commons file fc3604aa-db09-46af-9692-f1f5378ad0aa (TCGA-49-AARQ.9A745E52-5B6D-4209-9A05-E30D8CE40A3E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).